Gene-level copy-number profile of tumor specimen ALCH-B3GT-TTP1-A from ALCHEMIST case ALCH-B3GT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.1 years (19,776 days).
Specimen ALCH-B3GT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7f823baa-cc9f-49f3-b720-24140f1c96fd.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3GT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,243 have no estimate.
https://portal.gdc.cancer.gov/files/675aa513-7088-4ada-b3cf-ef5febda0b85

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 590; copy number 2: 57,326; copy number 3: 336; copy number 4: 6; copy number 5: 14; copy number 6: 6; copy number 8: 5; copy number 11: 9; copy number 12: 1; copy number 27: 21.

Homozygous deletions (total copy number 0; autosomes only): 63 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,434,861–1,442,882, 1 gene: VWA1.
- chr1:149,606,334–149,705,716, 5 genes (within-gene range 0–2): LINC00869, AC242842.2, AC242842.1, RNVU1-30, FAM91A2P.
- chr1:149,700,151–149,700,296, 1 gene (within-gene range 0–2): RNU1-68P.
- chr2:127,931,327–127,931,440, 1 gene: AC012306.1.
- chr4:39,973,128–40,021,517, 3 genes (within-gene range 0–2): AC098591.3, PABPC1P1, KRT18P25.
- chr6:58,386,799–58,386,961, 1 gene: AL603755.1.
- chr7:45,769,105–45,815,263, 2 genes (within-gene range 0–2): GTF2IP13, RNU6-241P.
- chr8:69,922,751–69,923,047, 1 gene: RN7SL675P.
- chr11:66,244,840–66,246,239, 1 gene: AP000759.1.
- chr13:45,060,729–45,061,086, 1 gene (within-gene range 0–2): RN7SKP3.
- chr14:100,143,957–100,159,645, 1 gene (within-gene range 0–2): DEGS2.
- chr15:25,169,337–25,220,578, 28 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27.
- chr15:92,417,547–92,417,689, 1 gene (within-gene range 0–2): AC090985.1.
- chr17:19,719,059–19,722,428, 1 gene: AC005722.3.
- chr17:79,833,156–79,839,440, 1 gene: CBX4.
- chr17:80,960,766–80,961,713, 1 gene (within-gene range 0–2): AC127496.4.
- chr18:62,650,308–62,650,601, 1 gene: RN7SL705P.
- chr19:4,472,297–4,502,208, 1 gene (within-gene range 0–2): HDGFL2.
- chr19:53,992,288–54,012,669, 1 gene: CACNG6.
- chr22:18,906,238–18,959,512, 4 genes (within-gene range 0–12): AC007326.4, PRODH, AC007326.5, AC007326.2.
- chr22:21,379,382–21,396,590, 5 genes: Metazoa_SRP, RIMBP3B, RN7SKP63, AP000552.3, Metazoa_SRP.
- chr22:35,717,872–35,729,483, 1 gene: APOL5.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 56 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–144,373,659, 30 genes, copy number 11–27: AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E.
- chr7:97,963,658–97,964,481, 2 genes, copy number 6: MIR5692A1, MIR5692C2.
- chr11:66,257,294–66,296,664, 10 genes, copy number 5: KLC2, AP001107.4, AP001107.8, AP001107.7, RAB1B, AP001107.1, AP001107.2, CNIH2, YIF1A, TMEM151A.
- chr11:102,306,112–102,313,829, 3 genes, copy number 5: AP000942.3, AP000942.4, RNU6-952P.
- chr13:112,313,467–112,321,758, 1 gene, copy number 6: LINC01043.
- chr17:42,270,517–42,311,943, 3 genes, copy number 6 (within-gene range 2–6): AC099811.1, AC099811.5, STAT5A.
- chr17:57,988,180–58,008,187, 5 genes, copy number 8 (within-gene range 3–8): AC015813.7, AC015813.2, AC015813.1, SRSF1, AC015813.5.
- chr19:1,039,997–1,065,572, 1 gene, copy number 5: ABCA7.
- chr22:18,906,028–18,914,238, 1 gene, copy number 12 (within-gene range 0–12): DGCR6.

Autosomal genes at a single copy (total copy number 1): 590. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
